Somatic mutation profile of tumor specimen TCGA-FD-A3SJ-01A (aliquot TCGA-FD-A3SJ-01A-12D-A22Z-08) from TCGA case TCGA-FD-A3SJ, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 59.2 years (21,615 days).
Specimen TCGA-FD-A3SJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ff442ad2-e65d-4bef-aae7-511b1fa4be82.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FD-A3SJ-10A (Blood Derived Normal), aliquot TCGA-FD-A3SJ-10A-01D-A22Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/67f925c6-c504-4533-9421-299ae5b1040d

The open-access MAF lists 265 somatic variants for this specimen: 195 protein-altering or splice-affecting, 64 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 168, Silent 64, Nonsense Mutation 12, Frame Shift Del 5, Splice Site 4, Intron 3, Translation Start Site 2, Frame Shift Ins 2, 5'Flank 2, Nonstop Mutation 1, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GCNT2 | c.1025A>G p.Y342C (on ENST00000379597 / NM_001374747.1; = p.Y340C on NM_001491.3) | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs786205577, COSV53944351; ClinVar: likely pathogenic; called by muse, mutect2
- PIK3CA | c.3140A>T p.H1047L | Missense Mutation (SNP) | VAF 41/97 reads (42%) | hotspot (GDC flag); SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 14/38 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934573, CM1212186, CM920673, COSV52661688, COSV52662386, COSV52713934, COSV52760886; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- AASDH | c.1007A>G p.N336S | Missense Mutation (SNP) | VAF 33/174 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52710569; called by muse, mutect2, varscan2
- ALPK3 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.103); catalogued as COSV51931525; called by muse, mutect2, varscan2
- ARFGEF3 | c.4900G>C p.E1634Q | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.575); catalogued as COSV52463055, COSV52470565; called by muse, mutect2, varscan2
- ARHGEF17 | c.3610G>A p.D1204N | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); catalogued as COSV55237986; called by muse, mutect2, varscan2
- ARID2 | c.2755C>G p.Q919E | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.023); catalogued as COSV57614388; called by muse, mutect2, varscan2
- ATF7IP | c.1732G>A p.E578K | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1351961049, COSV53777550; called by muse, mutect2, varscan2
- BICD2 | c.1594G>A p.E532K | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63550874; called by muse, mutect2, varscan2
- C3 | c.4535G>A p.R1512H | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.329); catalogued as rs142868256; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- C7orf33 | c.530G>A p.S177N | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.192); catalogued as COSV61024034; called by muse, mutect2, varscan2
- CABP4 | c.40C>G p.L14V | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.014); catalogued as COSV56888084; called by muse, mutect2, varscan2
- CACNG2 | c.43G>A p.V15I | Missense Mutation (SNP) | VAF 60/123 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.233); catalogued as COSV55640927; called by muse, mutect2, varscan2
- CCDC146 | c.1621G>A p.E541K | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV53555550; called by muse, mutect2
- CCNT1 | c.1178G>T p.R393L | Missense Mutation (SNP) | VAF 33/202 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56063430, COSV56066097; called by muse, mutect2, varscan2
- CD244 | c.817G>C p.D273H (on ENST00000368033 / NM_001166663.2; = p.D268H on NM_016382.4) | Missense Mutation (SNP) | VAF 151/237 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.341); catalogued as COSV59241531; called by muse, mutect2, varscan2
- CDC16 | c.1849G>C p.D617H | Missense Mutation (SNP) | VAF 39/57 reads (68%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV52961093, COSV52961838; called by muse, mutect2, varscan2
- CDHR1 | c.2159C>G p.S720C | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV60566367; called by muse, mutect2, varscan2
- CDR1 | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs267606368, COSV65164044; called by muse, mutect2, varscan2
- CFAP65 | c.4286C>G p.S1429C | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.796); catalogued as rs1397309949; called by muse, mutect2
- CHD2 | c.5153+1G>A p.X1718_splice | Splice Site (SNP) | VAF 18/45 reads (40%) | catalogued as COSV67710268, COSV67714339; called by muse, mutect2, varscan2
- CLASP2 | c.2179A>G p.R727G | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as rs777731869, COSV56293606; called by muse, mutect2, varscan2
- CNTNAP3 | c.2251A>G p.I751V | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs752272588; called by muse, mutect2, varscan2
- COL22A1 | c.3072G>A p.K1024= | Splice Region (SNP) | VAF 13/87 reads (15%) | catalogued as COSV57360051; called by muse, mutect2, varscan2
- CRX | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.084); catalogued as COSV55760047; called by muse, mutect2, varscan2
- CSTF2T | c.1315G>C p.E439Q | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.37); catalogued as COSV58657505; called by muse, mutect2, varscan2
- CYP27B1 | c.742G>T p.G248W | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.982); catalogued as COSV56986594; called by muse, mutect2, varscan2
- DDA1 | c.198+1G>T p.X66_splice | Splice Site (SNP) | VAF 35/216 reads (16%) | catalogued as COSV63290130; called by muse, mutect2, varscan2
- DDX31 | c.1138A>T p.S380C | Missense Mutation (SNP) | VAF 42/160 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.086); catalogued as COSV60139621; called by muse, mutect2, varscan2
- DEK | c.533G>C p.R178T | Missense Mutation (SNP) | VAF 15/260 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); catalogued as COSV55239739; called by muse, mutect2
- DLC1 | c.2062T>A p.S688T (on ENST00000276297 / NM_001348081.2; = p.S251T on NM_006094.5) | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.021); catalogued as COSV52327350; called by muse, mutect2, varscan2
- DNAH10 | c.7152G>T p.M2384I (on ENST00000409039; = p.M2323I on NM_207437.3) | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV69001311; called by muse, mutect2, varscan2
- EED | c.810G>C p.M270I | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs905981541, COSV54558500; called by muse, mutect2, varscan2
- EED | c.811A>T p.M271L | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV54558508; called by muse, mutect2, varscan2
- EMB | c.953G>A p.R318K | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1311637717, COSV57484461; called by muse, mutect2, varscan2
- ERBB3 | c.220C>T p.L74F | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.516); catalogued as COSV57263029; called by muse, mutect2, varscan2
- FGF13 | c.295T>A p.Y99N | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV59550216; called by muse, mutect2, varscan2
- FLNB | c.1473G>A p.M491I | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV55894975; called by muse, mutect2, varscan2
- FN1 | c.6013C>G p.L2005V | Missense Mutation (SNP) | VAF 37/68 reads (54%) | SIFT tolerated (0.62); PolyPhen benign (0.377); catalogued as COSV60563988; called by muse, mutect2, varscan2
- FUT2 | c.40C>A p.H14N | Missense Mutation (SNP) | VAF 64/264 reads (24%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.143); catalogued as COSV67179785; called by muse, mutect2, varscan2
- FUT8 | c.754A>G p.T252A (on ENST00000360689 / NM_001371534.1; = p.T89A on NM_004480.4) | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs1343102551, COSV61291009; called by muse, mutect2, varscan2
- GALNTL6 | c.192G>C p.L64F | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.467); catalogued as COSV72488723, COSV72490836; called by muse, mutect2, varscan2
- GARNL3 | c.2172C>G p.I724M | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.462); catalogued as COSV59230462; called by muse, mutect2, varscan2
- GK2 | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs776385662, COSV62625914, COSV62628380; called by muse, mutect2, varscan2
- GPATCH8 | c.2596T>A p.S866T | Missense Mutation (SNP) | VAF 39/142 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.344); catalogued as COSV59198348; called by muse, mutect2, varscan2
- GPR150 | c.110C>G p.S37C | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV66168600; called by muse, mutect2, varscan2
- GRM1 | c.1413G>C p.E471D | Missense Mutation (SNP) | VAF 60/177 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.416); catalogued as COSV51314152; called by muse, mutect2, varscan2
- GTF2IRD2 | c.1883A>G p.N628S | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs782361982, COSV100736437; called by muse, mutect2, varscan2
- H2AC21 | c.106C>G p.R36G | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.786); catalogued as COSV58613186; called by muse, mutect2, varscan2
- HAS1 | c.884G>A p.C295Y | Missense Mutation (SNP) | VAF 54/223 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55789662; called by muse, mutect2, varscan2
- HGFAC | c.685G>C p.E229Q | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.62); PolyPhen benign (0.013); catalogued as COSV58756935; called by muse, mutect2
- ILF3 | c.2360C>T p.S787L | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT tolerated (0.57); PolyPhen benign (0.028); catalogued as rs773828957, COSV51562276; called by muse, mutect2, varscan2
- IQCF2 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.299); catalogued as rs1174099419, COSV60761010, COSV60761932; called by muse, mutect2, varscan2
- IRX4 | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51471007; called by muse, mutect2, varscan2
- ITM2C | c.150G>C p.K50N | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.014); catalogued as COSV58400290; called by muse, mutect2
- KCNAB2 | c.883A>G p.I295V | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs745486467, COSV51239127; called by muse, mutect2, varscan2
- KDM6A | c.410G>T p.G137V | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV65038446; called by muse, mutect2, varscan2
- KMT2A | c.4012+1G>A p.X1338_splice | Splice Site (SNP) | VAF 11/25 reads (44%) | catalogued as COSV63292409; called by muse, mutect2, varscan2
- KMT2C | c.3923C>G p.S1308* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | catalogued as COSV51424708; called by muse, mutect2
- LAMB1 | c.2069C>T p.S690F | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.7); PolyPhen benign (0.005); catalogued as rs1170055443, COSV55970028; called by muse, mutect2, varscan2
- LEPR | c.2278C>G p.L760V | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as rs200160154, COSV60764384; called by muse, mutect2, varscan2
- LMBRD2 | c.110G>C p.G37A | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.94); PolyPhen benign (0.022); catalogued as COSV56952763; called by muse, mutect2
- LPCAT1 | c.803A>T p.Q268L | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV52041220; called by muse, mutect2, varscan2
- LRP1 | c.1068G>T p.Q356H | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV54525602; called by muse, mutect2, varscan2
- LRP12 | c.473C>T p.S158L | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV52634477; called by muse, mutect2
- MAN2A1 | c.1948C>T p.L650F | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs142458296; called by muse, mutect2, varscan2
- MAPKBP1 | c.2512G>A p.V838M (on ENST00000456763 / NM_001128608.2; = p.V832M on NM_014994.3) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs747137432, COSV52966950; called by muse, mutect2, varscan2
- MEFV | c.1336G>C p.E446Q | Missense Mutation (SNP) | VAF 20/163 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.023); catalogued as COSV54823986, COSV54827429; called by muse, mutect2, varscan2
- MGAT4A | c.249G>C p.L83F | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as COSV53850723; called by muse, mutect2, varscan2
- MGAT4A | c.119A>T p.E40V | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as COSV53850727; called by muse, mutect2, varscan2
- MGAT4A | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.21); catalogued as COSV53850733; called by muse, mutect2, varscan2
- MGMT | c.691G>T p.G231C (on ENST00000306010; = p.G200C on NM_002412.5) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.43); catalogued as rs751884076, COSV60034589; called by muse, mutect2, varscan2
- MICAL2 | c.643G>C p.E215Q | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.373); catalogued as COSV56322252; called by muse, mutect2, varscan2
- MMACHC | c.16G>T p.A6S | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs747875672, COSV68985485; called by muse, mutect2, varscan2
- MRPL40 | c.591G>C p.K197N | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54277546, COSV54279671; called by muse, mutect2, varscan2
- MRPL58 | c.402C>G p.I134M | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV56901917; called by muse, mutect2, varscan2
- MTIF2 | c.820C>G p.Q274E | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.021); catalogued as COSV55054187; called by muse, mutect2, varscan2
- MUC16 | c.887C>T p.S296L | Missense Mutation (SNP) | VAF 46/95 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.51); catalogued as COSV67442269; called by muse, mutect2, varscan2
- MXD1 | c.464C>G p.S155C | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52480865, COSV52480964; called by muse, mutect2
- MYH13 | c.4053T>A p.Y1351* | Nonsense Mutation (SNP) | VAF 21/111 reads (19%) | catalogued as rs1393616202; called by muse, mutect2, varscan2
- NFATC2 | c.865G>A p.G289S | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as rs748599482, COSV65354285; called by muse, mutect2, varscan2
- NKTR | c.1636C>G p.R546G | Missense Mutation (SNP) | VAF 41/165 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.09); catalogued as COSV51775245; called by muse, mutect2, varscan2
- NME8 | c.1404G>C p.Q468H | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as COSV52255271; called by muse, mutect2, varscan2
- NTS | c.185G>T p.C62F | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55457128; called by muse, mutect2, varscan2
- OGN | c.440G>C p.R147T | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV52761872; called by muse, mutect2, varscan2
- OOSP2 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.484); catalogued as COSV53930029; called by muse, mutect2, varscan2
- OR10Q1 | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs778216887, COSV57469754; called by muse, mutect2, varscan2
- OR11H4 | c.604G>T p.A202S | Missense Mutation (SNP) | VAF 68/169 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.15); catalogued as COSV59560915; called by muse, mutect2, varscan2
- OR51G1 | c.898C>A p.Q300K | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.543); catalogued as COSV58970755; called by muse, mutect2, varscan2
- OR5D18 | c.803C>G p.S268C | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61737788, COSV61738604; called by muse, mutect2, varscan2
- OTOGL | c.2224G>T p.A742S (on ENST00000547103; = p.A733S on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as COSV72007477; called by muse, mutect2, varscan2
- OVGP1 | c.1291G>T p.G431W | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.221); catalogued as COSV63860071; called by muse, mutect2, varscan2
- PBLD | c.647G>C p.R216T | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53267253; called by muse, mutect2, varscan2
- PBX1 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 9/135 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63348117; called by muse, mutect2
- PCDHA12 | c.1624G>T p.V542L | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.089); catalogued as COSV56544132; called by muse, mutect2, varscan2
- PCDHA13 | c.1903C>T p.R635C | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs781800470, COSV56544142; called by muse, mutect2, varscan2
- PCDHA6 | c.557G>A p.S186N | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.01); catalogued as COSV65357683; called by muse, mutect2, varscan2
- PCDHB12 | c.1465T>A p.S489T | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.922); catalogued as COSV53400959; called by muse, mutect2, varscan2
- PCSK6 | c.949G>T p.G317W | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59344604; called by muse, mutect2, varscan2
- PGBD1 | c.1506C>G p.F502L | Missense Mutation (SNP) | VAF 49/169 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.19); catalogued as rs1240897569, COSV52556038; called by muse, mutect2, varscan2
- PGBD1 | c.1846G>A p.E616K | Missense Mutation (SNP) | VAF 54/179 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.133); catalogued as COSV52556058; called by muse, mutect2, varscan2
- PIGK | c.551C>T p.A184V | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs780683566, COSV63063590; called by muse, mutect2, varscan2
- PLOD2 | c.1730A>T p.D577V | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV51469020; called by muse, mutect2, varscan2
- PLPPR1 | c.335G>C p.G112A | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.994); catalogued as COSV66457715; called by muse, mutect2, varscan2
- PNLIP | c.146A>G p.K49R | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as COSV65041975; called by muse, mutect2, varscan2
- POTEH | c.211T>C p.W71R | Missense Mutation (SNP) | VAF 52/252 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.127); catalogued as COSV58886914; called by muse, varscan2
- PPFIA3 | c.2258C>T p.S753F | Missense Mutation (SNP) | VAF 73/194 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as COSV100495211, COSV61954612; called by muse, mutect2, varscan2
- PPFIBP1 | c.208T>A p.L70M | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as COSV57298490; called by muse, mutect2, varscan2
- PPM1G | c.398A>T p.D133V | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.865); catalogued as COSV59771817; called by muse, mutect2, varscan2
- PREX2 | c.2302C>T p.L768F | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.034); catalogued as COSV55787000, COSV55798141; called by muse, mutect2, varscan2
- PRG3 | c.157A>T p.T53S | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.056); catalogued as COSV54664657; called by muse, mutect2, varscan2
- PSD | c.865G>A p.D289N | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50060731; called by muse, mutect2, varscan2
- PSG2 | c.587C>G p.S196C | Missense Mutation (SNP) | VAF 129/986 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV61546517; called by muse, mutect2, varscan2
- RASSF9 | c.739C>A p.L247I | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV63436017; called by muse, mutect2, varscan2
- RFLNA | c.510C>G p.I170M (on ENST00000546355 / NM_001365156.1; = p.I89M on NM_181709.4) | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV58039006; called by muse, mutect2, varscan2
- RFX3 | c.1510C>T p.H504Y | Missense Mutation (SNP) | VAF 43/81 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as rs865829359, COSV56524790; called by muse, mutect2, varscan2
- RGS22 | c.1441G>C p.D481H | Missense Mutation (SNP) | VAF 6/127 reads (5%) | SIFT tolerated (0.68); PolyPhen benign (0.018); catalogued as COSV62667474; called by muse, mutect2
- RGS3 | c.2543C>T p.A848V (on ENST00000350696 / NM_001282923.2; = p.A567V on NM_130795.4) | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as rs968451828, COSV59517393; called by muse, mutect2, varscan2
- RIPK1 | c.124A>G p.M42V | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52531683; called by muse, mutect2, varscan2
- RIPK4 | c.1750G>A p.E584K (on ENST00000352483; = p.E536K on NM_020639.3) | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.096); catalogued as COSV60191109; called by muse, mutect2, varscan2
- RNF180 | c.673C>A p.H225N | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56962132, COSV56965026; called by muse, mutect2, varscan2
- ROPN1L | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV56873102; called by muse, mutect2, varscan2
- RPL3L | c.879G>A p.M293I | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51908397; called by muse, mutect2, varscan2
- RPTOR | c.131C>G p.S44C | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.088); catalogued as COSV60818239; called by muse, mutect2, varscan2
- RPUSD4 | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 71/161 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.649); catalogued as COSV53600284; called by muse, mutect2, varscan2
- SCAPER | c.2386C>G p.L796V | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV57753838; called by muse, varscan2
- SCN10A | c.4495G>C p.D1499H | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as COSV71862649; called by muse, varscan2
- SELENON | c.1402C>T p.L468F | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.07); catalogued as COSV62526073, COSV62526300; called by muse, mutect2, varscan2
- SHARPIN | c.940C>T p.Q314* | Nonsense Mutation (SNP) | VAF 13/32 reads (41%) | catalogued as rs201083501; called by muse, mutect2, varscan2
- SHE | c.646C>T p.Q216* | Nonsense Mutation (SNP) | VAF 26/89 reads (29%) | catalogued as COSV59070872; called by muse, mutect2, varscan2
- SIVA1 | c.190G>A p.V64I | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as rs754034141, COSV57332234; called by muse, mutect2, varscan2
- SLC15A1 | c.1994T>C p.I665T | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV64733678; called by muse, mutect2, varscan2
- SLC35G3 | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 101/267 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.426); catalogued as rs530351643, COSV52012727; called by muse, mutect2, varscan2
- SLC6A15 | c.1042G>T p.A348S | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV57029568; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1976C>T p.T659M (on ENST00000540229 / NM_001371097.1; = p.T598M on NM_001009562.4) | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs753900713, COSV67449849; called by muse, mutect2, varscan2
- SLCO1C1 | c.1402C>A p.H468N | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.009); catalogued as COSV56867944, COSV56873115; called by mutect2, varscan2
- SLCO2A1 | c.125A>T p.Q42L | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60489376; called by muse, mutect2, varscan2
- ST18 | c.22A>G p.K8E | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as COSV52508982; called by muse, mutect2, varscan2
- ST6GALNAC5 | c.741G>C p.R247S | Missense Mutation (SNP) | VAF 42/129 reads (33%) | PolyPhen possibly damaging (0.475); catalogued as COSV59572213; called by muse, mutect2, varscan2
- STAG1 | c.1060C>G p.L354V | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as COSV52623686; called by muse, mutect2, varscan2
- SUPT7L | c.1006C>G p.L336V | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.458); catalogued as COSV53117541; called by muse, mutect2, varscan2
- SYT4 | c.934C>G p.R312G | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54904035; called by muse, mutect2, varscan2
- TAF4B | c.665T>A p.L222Q | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.48); catalogued as COSV52310016; called by muse, mutect2, varscan2
- TCHH | c.5374G>C p.E1792Q | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.062); catalogued as COSV64277647; called by muse, mutect2, varscan2
- TCHH | c.5251G>C p.E1751Q | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.915); catalogued as COSV64274386, COSV64277651; called by muse, mutect2, varscan2
- TCN2 | c.484C>G p.L162V | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.278); catalogued as rs1330557305, COSV53193042; called by muse, mutect2, varscan2
- TENM2 | c.6816G>C p.Q2272H (on ENST00000518659 / NM_001122679.2; = p.Q2033H on NM_001080428.3) | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1248970643, COSV69122338; called by muse, mutect2, varscan2
- TIAM2 | c.2206C>T p.H736Y | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59704118; called by muse, mutect2, varscan2
- TMEM132A | c.481C>T p.R161W | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as rs374191784; called by muse, mutect2, varscan2
- TMEM132D | c.938G>C p.R313T | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV70622169; called by muse, mutect2, varscan2
- TMEM200A | c.1143G>T p.Q381H | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.459); catalogued as COSV51659565; called by muse, mutect2, varscan2
- TNIK | c.1310G>A p.R437K | Missense Mutation (SNP) | VAF 56/174 reads (32%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.815); catalogued as COSV52695706; called by muse, mutect2, varscan2
- TRIM68 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs1398635983, COSV56170038; called by muse, mutect2, varscan2
- TRPC6 | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV60260880; called by muse, mutect2, varscan2
- TRPM2 | c.1534G>A p.E512K | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.149); catalogued as COSV55967826; called by muse, mutect2, varscan2
- TTN | c.60418C>G p.P20140A (on ENST00000591111; = p.P12716A on NM_003319.4) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | PolyPhen probably damaging (0.997); catalogued as COSV60340967; called by muse, mutect2, varscan2
- UBASH3A | c.748G>C p.E250Q | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52316087, COSV52316689; called by muse, mutect2, varscan2
- UVRAG | c.1771G>A p.G591R | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs375334287; called by muse, mutect2, varscan2
- XDH | c.1993G>A p.G665R | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65151133; called by muse, mutect2, varscan2
- ZAP70 | c.157G>C p.D53H | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.496); catalogued as COSV99385547; called by muse, mutect2, varscan2
- ZBTB41 | c.1205C>G p.S402C | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV66360100; called by muse, mutect2, varscan2
- ZC3HC1 | c.226G>C p.E76Q | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV61300232; called by muse, mutect2, varscan2
- ZMIZ1 | c.2186A>C p.D729A | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.067); catalogued as COSV57903686; called by muse, mutect2, varscan2
- ZMYM1 | c.2813G>C p.R938T | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.149); catalogued as COSV63253680; called by muse, mutect2
- ZNF229 | c.1621G>A p.G541R | Missense Mutation (SNP) | VAF 150/241 reads (62%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.522); catalogued as COSV52162318, COSV52164846; called by muse, mutect2, varscan2
- ZNF33B | c.2302C>T p.Q768* | Nonsense Mutation (SNP) | VAF 27/218 reads (12%) | catalogued as rs1196576631; called by muse, mutect2, varscan2
- ZNF536 | c.344C>A p.S115Y | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62831454, COSV62833755; called by muse, mutect2
- ZNF548 | c.60G>T p.E20D | Missense Mutation (SNP) | VAF 102/280 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.25); catalogued as COSV60241983; called by muse, mutect2, varscan2
- ZNF681 | c.808A>G p.T270A | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.123); catalogued as rs750151055, COSV68075607; called by muse, mutect2, varscan2
- APOA2 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- C2CD5 | c.1260C>G p.I420M | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CLDN8 | c.539C>A p.A180D | Missense Mutation (SNP) | VAF 4/71 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.515); called by muse, mutect2
- DST | c.11059G>T p.E3687* (on ENST00000361203 / NM_001374722.1; = p.E1275* on NM_015548.5) | Nonsense Mutation (SNP) | VAF 10/79 reads (13%) | called by muse, mutect2
- EIF4ENIF1 | c.82del p.H28Ifs*11 | Frame Shift Del (DEL) | VAF 31/60 reads (52%) | called by mutect2, pindel, varscan2
- FOXD4L4 | c.764C>G p.P255R | Missense Mutation (SNP) | VAF 14/167 reads (8%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.937); called by muse, mutect2
- GAA | c.1318A>G p.M440V | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- GABPA | c.628A>G p.I210V | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- GCNA | c.80C>G p.S27* | Nonsense Mutation (SNP) | VAF 17/34 reads (50%) | called by muse, mutect2, varscan2
- IGKV1D-16 | c.160T>C p.W54R | Missense Mutation (SNP) | VAF 60/249 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KBTBD7 | c.1879C>T p.Q627* | Nonsense Mutation (SNP) | VAF 33/109 reads (30%) | called by muse, mutect2, varscan2
- KCNQ4 | c.315-1G>C p.X105_splice | Splice Site (SNP) | VAF 4/33 reads (12%) | called by muse, mutect2
- MAP3K15 | c.2969del p.G990Afs*66 | Frame Shift Del (DEL) | VAF 18/57 reads (32%) | called by mutect2, pindel, varscan2
- NPAS4 | c.550G>T p.G184* | Nonsense Mutation (SNP) | VAF 25/129 reads (19%) | called by muse, mutect2, varscan2
- OR51I2 | c.545dup p.D183Rfs*9 | Frame Shift Ins (INS) | VAF 31/78 reads (40%) | called by mutect2, pindel, varscan2
- PAPPA2 | c.1543G>T p.G515* | Nonsense Mutation (SNP) | VAF 13/137 reads (9%) | called by muse, mutect2
- PPP3R1 | c.512G>C p.*171Sext*17 | Nonstop Mutation (SNP) | VAF 6/30 reads (20%) | called by muse, mutect2, varscan2
- PPP6R3 | c.863dup p.I289Dfs*30 | Frame Shift Ins (INS) | VAF 48/151 reads (32%) | called by mutect2, pindel, varscan2
- PRDM16 | c.406del p.E136Kfs*75 | Frame Shift Del (DEL) | VAF 21/88 reads (24%) | called by mutect2, pindel, varscan2
- RBM15 | c.476C>G p.S159* | Nonsense Mutation (SNP) | VAF 21/57 reads (37%) | called by muse, mutect2, varscan2
- RIF1 | c.6232G>C p.G2078R | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.029); called by muse, mutect2
- TNKS1BP1 | c.289del p.L97Ffs*34 | Frame Shift Del (DEL) | VAF 7/43 reads (16%) | called by mutect2, pindel, varscan2
- WNK3 | c.3704C>T p.A1235V | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.162); called by muse, mutect2
- ZNF317 | c.1773del p.W591* | Frame Shift Del (DEL) | VAF 14/46 reads (30%) | called by mutect2, pindel, varscan2
- ZNF7 | c.2024C>G p.S675* | Nonsense Mutation (SNP) | VAF 66/154 reads (43%) | called by muse, mutect2, varscan2
- A1BG | c.810C>T p.A270= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as rs140428520, COSV99568556; called by muse, mutect2, varscan2
- ANXA8L1 | c.975C>T p.S325= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs781982198; called by muse, mutect2, varscan2
- ARHGEF17 | c.3867G>A p.L1289= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as rs539172281, COSV55237998; called by muse, mutect2, varscan2
- ARMH3 | c.1800T>C p.F600= | Silent (SNP) | VAF 55/247 reads (22%) | catalogued as COSV64238113; called by muse, mutect2, varscan2
- BRD9 | c.696A>T p.A232= | Silent (SNP) | VAF 27/164 reads (16%) | catalogued as COSV60250027; called by muse, mutect2, varscan2
- C10orf88 | c.621G>A p.L207= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as rs936895319, COSV64404422; called by muse, mutect2, varscan2
- CGN | c.804G>A p.Q268= | Silent (SNP) | VAF 13/44 reads (30%) | called by mutect2, varscan2
- CLCN1 | c.1593G>T p.A531= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV58374359; called by muse, mutect2, varscan2
- CNTN1 | c.2814G>T p.T938= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as COSV61639599, COSV61640204; called by muse, mutect2, varscan2
- COL6A3 | c.618T>G p.L206= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV55109124; called by muse, mutect2, varscan2
- COPG1 | c.891C>T p.S297= | Silent (SNP) | VAF 25/140 reads (18%) | catalogued as COSV59116476; called by muse, mutect2, varscan2
- CUBN | c.5130C>T p.S1710= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as rs750798030, COSV64726949; called by muse, mutect2, varscan2
- DEDD | c.180C>T p.L60= | Silent (SNP) | VAF 66/97 reads (68%) | catalogued as rs1280275463, COSV63502712; called by muse, mutect2, varscan2
- DENND2A | c.2004G>C p.V668= | Silent (SNP) | VAF 22/98 reads (22%) | catalogued as COSV52058784; called by muse, mutect2, varscan2
- DPEP2 | c.1182G>A p.L394= | Silent (SNP) | VAF 32/236 reads (14%) | catalogued as COSV52056086; called by muse, mutect2, varscan2
- ERCC3 | c.1704A>G p.L568= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as COSV53429893; called by muse, mutect2, varscan2
- EYA1 | c.573A>T p.T191= | Silent (SNP) | VAF 15/111 reads (14%) | catalogued as COSV58173853; called by muse, mutect2, varscan2
- FAM13C | c.879C>T p.I293= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as rs1202300052, COSV53255838; called by muse, mutect2, varscan2
- FCRL3 | c.1992G>A p.Q664= | Silent (SNP) | VAF 36/94 reads (38%) | catalogued as COSV63844675; called by muse, mutect2, varscan2
- GDF15 | c.18C>T p.L6= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as COSV99416181; called by muse, mutect2, varscan2
- GDF5 | c.1117C>T p.L373= | Silent (SNP) | VAF 69/213 reads (32%) | catalogued as COSV65503523; called by muse, mutect2, varscan2
- GLI2 | c.2106G>A p.L702= (on ENST00000361492 / NM_001374353.1; = p.L719= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV58051213; called by muse, mutect2, varscan2
- IFIT3 | c.1281G>A p.Q427= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as COSV51080675; called by muse, mutect2, varscan2
- IMPG2 | c.735C>T p.F245= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV51985553; called by muse, mutect2, varscan2
- ITGB4 | c.2742C>G p.L914= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV52332551; called by muse, mutect2, varscan2
- JPH1 | c.1671G>A p.L557= | Silent (SNP) | VAF 18/116 reads (16%) | catalogued as COSV60614648; called by muse, mutect2, varscan2
- KCNA4 | c.1575G>C p.V525= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as COSV60255873; called by muse, mutect2, varscan2
- KDM5B | c.3753A>T p.A1251= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as COSV52512809; called by muse, mutect2, varscan2
- KIF4B | c.2664G>T p.L888= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as COSV70531300; called by muse, mutect2, varscan2
- KRBA1 | c.1062C>G p.L354= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs1255716735; called by muse, mutect2
- KRT5 | c.1392C>T p.D464= | Silent (SNP) | VAF 31/143 reads (22%) | catalogued as rs531299414, COSV52858742; called by muse, mutect2, varscan2
- LGR4 | c.648G>C p.L216= | Silent (SNP) | VAF 33/82 reads (40%) | catalogued as rs1240392396, COSV64866250; called by muse, mutect2, varscan2
- MAP1LC3A | c.237C>T p.F79= | Silent (SNP) | VAF 27/103 reads (26%) | catalogued as COSV54166393; called by muse, mutect2, varscan2
- MATN2 | c.513G>C p.G171= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV54719211, COSV54719561; called by muse, mutect2, varscan2
- MCHR1 | c.660C>T p.S220= | Silent (SNP) | VAF 28/80 reads (35%) | catalogued as COSV50762910; called by muse, mutect2, varscan2
- NPAP1 | c.954C>G p.P318= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as COSV100274837, COSV61505716, COSV61510990; called by muse, mutect2, varscan2
- NPAS4 | c.1155T>C p.S385= | Silent (SNP) | VAF 31/231 reads (13%) | catalogued as COSV60652798; called by muse, mutect2, varscan2
- OR10AG1 | c.147C>T p.P49= | Silent (SNP) | VAF 49/105 reads (47%) | catalogued as COSV56632459, COSV56633123, COSV56634675; called by muse, mutect2, varscan2
- OR4K17 | c.402C>T p.T134= | Silent (SNP) | VAF 11/107 reads (10%) | catalogued as COSV59649118; called by muse, mutect2, varscan2
- OR8A1 | c.738C>T p.A246= | Silent (SNP) | VAF 30/62 reads (48%) | catalogued as rs745564232, COSV52510388; called by muse, mutect2, varscan2
- ORC1 | c.444G>A p.L148= | Silent (SNP) | VAF 66/149 reads (44%) | catalogued as rs570939314, COSV65365165; called by muse, mutect2, varscan2
- PAPPA2 | c.2289A>G p.P763= | Silent (SNP) | VAF 22/399 reads (6%) | catalogued as COSV62785427; called by muse, mutect2
- PENK | c.576C>T p.G192= | Silent (SNP) | VAF 62/142 reads (44%) | catalogued as rs145346210; called by muse, mutect2, varscan2
- PFKL | c.2342G>A p.*781= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as rs1568976746; called by muse, mutect2
- PLEKHG5 | c.2067G>A p.L689= (on ENST00000400915 / NM_001042663.3; = p.L652= on NM_020631.6) | Silent (SNP) | VAF 41/187 reads (22%) | catalogued as COSV61069647; called by muse, mutect2, varscan2
- PON3 | c.954C>T p.T318= | Silent (SNP) | VAF 31/79 reads (39%) | catalogued as rs369650254; called by muse, mutect2, varscan2
- PRUNE2 | c.585G>C p.L195= | Silent (SNP) | VAF 16/105 reads (15%) | catalogued as COSV65029572; called by muse, mutect2, varscan2
- RASAL1 | c.723G>A p.E241= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as rs759785196, COSV55659694; called by muse, mutect2, varscan2
- RELL1 | c.66G>A p.V22= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV58454447; called by muse, mutect2, varscan2
- RNF213 | c.9699C>T p.V3233= | Silent (SNP) | VAF 24/93 reads (26%) | catalogued as COSV60408517; called by muse, mutect2, varscan2
- RPS20 | c.39G>A p.P13= | Silent (SNP) | VAF 11/118 reads (9%) | catalogued as rs1215073060, COSV50537165; called by muse, mutect2, varscan2
- SEMA3D | c.2184C>T p.D728= | Silent (SNP) | VAF 17/85 reads (20%) | catalogued as COSV52404320; called by muse, mutect2, varscan2
- SIDT2 | c.2055C>T p.Y685= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs757263614, COSV54056303; called by muse, mutect2, varscan2
- SLC45A1 | c.510G>T p.S170= | Silent (SNP) | VAF 15/78 reads (19%) | catalogued as COSV57100218; called by muse, mutect2, varscan2
- SLC5A9 | c.1227C>T p.F409= | Silent (SNP) | VAF 33/83 reads (40%) | catalogued as rs1416027669, COSV52585573; called by muse, mutect2, varscan2
- SPEG | c.2469C>G p.P823= | Silent (SNP) | VAF 38/86 reads (44%) | catalogued as COSV56679450; called by muse, mutect2, varscan2
- TCP11L2 | c.402A>G p.E134= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as COSV54432528; called by muse, mutect2, varscan2
- THEMIS2 | c.747G>A p.L249= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as COSV61078452; called by muse, mutect2, varscan2
- TRAF6 | c.762G>A p.Q254= | Silent (SNP) | VAF 29/89 reads (33%) | catalogued as COSV61923218; called by muse, mutect2, varscan2
- TRUB1 | c.729C>T p.F243= | Silent (SNP) | VAF 32/89 reads (36%) | catalogued as COSV53929210; called by muse, mutect2, varscan2
- VPS52 | c.876G>C p.L292= | Silent (SNP) | VAF 31/76 reads (41%) | catalogued as COSV71403641; called by muse, mutect2, varscan2
- ZC3H7A | c.2442G>A p.E814= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as rs200304212, COSV63271371; called by muse, mutect2, varscan2
- ZNF606 | c.894C>T p.F298= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as rs1220180538, COSV62049089; called by muse, mutect2, varscan2
- ZP2 | c.1773G>A p.Q591= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as COSV54816826; called by muse, mutect2, varscan2
- ADARB2 | c.101-177538C>T | Intron (SNP) | VAF 18/48 reads (38%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65497981 A>G | 5'Flank (SNP) | VAF 56/130 reads (43%) | catalogued as rs553137490; called by muse, mutect2, varscan2
- CPLANE1 | c.*2887G>A | 3'UTR (SNP) | VAF 10/85 reads (12%) | catalogued as rs751975523, COSV57073921; called by muse, mutect2, varscan2
- NFATC3 | c.3107-12009C>T | Intron (SNP) | VAF 6/53 reads (11%) | catalogued as COSV60479551; called by mutect2, varscan2
- SIAH1 | chr16:48365424 ins A | 5'Flank (INS) | VAF 10/30 reads (33%) | called by mutect2, pindel, varscan2
- VKORC1 | c.173+177G>C | Intron (SNP) | VAF 26/74 reads (35%) | catalogued as COSV56231803, COSV56232505; called by muse, mutect2, varscan2
